Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7102, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7102-01A (Primary Tumor).

[page 1 of 2]
**** Case imported from legacy computer system. The format of this report does not match the original case. ****
**** For cases prior to [REDACTED], the section "SPECIMEN" may have been added. ****

DIAGNOSIS

- (A) PROXIMAL MARGIN V-3:
Peripheral nerve, no tumor present.
- (B) LINGUAL MARGIN:
Segment of nerve, no tumor present.
- (C) BILATERAL NECK DISSECTION RIGHT AND LEFT SUBMANDIBULAR GLAND, SUBTOTAL GLOSSECTOMY OF FLOOR OF MOUTH RESECTION:
SQUAMOUS CARCINOMA GRADE 3 OF FLOOR OF MOUTH, 7 MM IN THICKNESS.
Moderate to severe dysplasia in margin designated lateral and inferior; other margins free of tumor.
Twelve left cervical lymph nodes, no tumor.
Left maxillary gland with chronic inflammation.
METASTATIC SQUAMOUS CARCINOMA IN 3 OF 12 RIGHT CERVICAL LYMPH NODES (NO EXTRANODAL EXTENSION MEASURE MORE THAN 3 MM IN LEVEL 2).
METASTATIC SQUAMOUS CARCINOMA IN SOFT TISSUES IN LEVEL 3.
Right submandibular gland, no tumor.
- (D) NEW RIGHT TONGUE MARGIN, STITCH NEW MARGIN:
Squamous mucosa, no tumor dysplasia present.
- (E) MUCOSAL SURFACE LEFT VENTRAL LATERAL FLOOR OF MOUTH:
Squamous mucosa, no dysplasia or tumor present.
- (F) TEETH
Gross diagnosis only.

Entire report and diagnosis completed by: [REDACTED]

GROSS DESCRIPTION

- (A) PROXIMAL MARGIN V-3, RIGHT SIDE - A pale yellow soft tissue fragment (0.6 x 0.2 x 0.1 cm). In toto in A. [REDACTED]
*FS/DX: SEGMENT OF NERVE, NO TUMOR PRESENT. [REDACTED]
- (B) LINGUAL MARGIN - A pale yellow soft tissue fragment (0.7 x 0.2 x 0.1 cm). In toto for frozen section in B. [REDACTED]
*FS/DX: SEGMENT OF NERVE, NO TUMOR PRESENT. [REDACTED]
- (C) BILATERAL NECK DISSECTION, RIGHT AND LEFT MANDIBULECTOMY, SUBTOTAL GLOSSECTOMY - Specimen overall dimension is 13.0 x 10.0 x 7.0 cm and includes the right rims of the mandible (9.0 x 3.0 x 0.9 cm), the left rim of the mandible (4.0 x 2.5 x 1.2 cm), most of the right medial half of the tongue (8.0 x 5.0 x 2.7 cm), a left right neck dissection (9.0 x 5.0 x 2.0 cm), and a left neck dissection (8.0 x 6.0 x 1.5 cm).
A tumor (4.7 x 2.7 cm) is present in the right aspect of the floor of the mouth. This tumor is ulcerated and mostly filled by necrotic material; it penetrates 0.7 cm into the underlying soft tissue. This tumor is 0.8 cm from the posterior mucosal margin of the floor of the mouth, 0.8 cm from the left anterior mucosal margin of the floor of the mouth, and 1.9 cm from the left

[page 2 of 2]
right alveolar mucosal margin. It involves and penetrates into the right aspect of the tongue.

In the mandible, there are six teeth on the right side (3 front teeth, 2 pre-molar, and 1 molar); and 6 teeth on the left side (3 anterior, 2 pre-molars, and 1 molar). The remaining buccal mucosa is pale pink, unremarkable.

Several lymph nodes are identified in the bilateral neck dissection. Section on the red some lymph nodes are grossly replaced by tumor. The largest 4.2 cm and the right side, level 2 and second largest 2.8 cm at right side level 1. All lymph nodes have been submitted.

INK CODE: Black-other resection margin.

SECTION CODE: C1, mucosal margin posterior floor of mouth and base of tongue, en face; C2, mucosal margin posterior floor of mouth, en face; C3, mucosal margin posterior, overlying alveolar ridge, en face; C4 and C5, right mucosal margin, on the exterior aspect of the mandible, en face; C6, anterior floor of mouth on left side; C7, left aspect of floor of mouth; C8, tumor in tongue, anterior aspect; C9 and C10, tumor and posterior aspect first node; C11, tumor and mucosa; C12 and C13, additional sections of tumor; C14-C16, level 1, left neck; C14, three lymph nodes; C15, one lymph node, serially sectioned; C16, salivary gland; C17, C18, level 2; C17, two lymph nodes; C18, three lymph nodes; C19-C21, level 3; C19, one lymph node, bisected; C20, four lymph nodes; C21, three lymph nodes. Right neck dissection from C22 to C29; C22-C24, level 1, right neck; C22, four lymph nodes; C23, one lymph node, grossly involved by tumor; C24, salivary gland; C25, C26, level 2, C25, one lymph node, grossly involved by tumor; C26, five lymph nodes; C27-C29, level 3, right side; C27, one lymph node, bisected, grossly involved by tumor; C28, three lymph nodes; C29, one lymph node.

NOTE: The salivary gland on the left side is 3.0 x 2.4 x 1.0 cm, grossly unremarkable and on the right side is 2.7 x 2.4 x 1.4 cm, gross unremarkable.

*FS/DX: FOCAL SEVERE DYSPLASIA AT MARGIN OF RESECTION.

(D) NEW RIGHT TONGUE DEEP MARGIN - A partial excision of tongue (4.5 x 1.7 x 1.6 cm). A stitch indicates the new margin. The tongue shows a small nodularity. However, no distinct tumor mass is identified.

INK CODE: Black-neutral margin.

SECTION CODE: D1-D9, sequential cross-section of specimen (perpendicular inked margin).

*FS/DX: SQUAMOUS MUCOSA, NO TUMOR PRESENT.

(E) MUCOSAL SURFACE LEFT VENTRAL LATERAL FLOOR OF MOUTH, INK TRUE LATERAL MARGIN - A single fragment of mucus measuring 1.5 cm in length, grossly unremarkable. The inked marks the true margin. The specimen is entirely submitted en face, labeled E.

*FS/DX: SQUAMOUS MUCOSA, NO TUMOR PRESENT.

(F) TEETH - Five intact to focally fragmented teeth (ranging from 1.0 x 0.5 x 0.4 cm to 2.1 x 1.0 x 0.7 cm). One of the teeth is covered by a metallic cap; a separate metallic cap is also present within the container. No tissue is submitted for histologic examination; this specimen is for gross examination only.

SNOMED CODES

M-80703 M-80706 T-51200 T-C4200

Source: NCI Genomic Data Commons file ca33ea27-f0e3-48c1-aa07-000e6a1061dd (TCGA-CV-7102.9C82C8DF-CF1A-45B9-B78F-237F245C470C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).